Somatic mutation profile of tumor specimen MP2PRT-PARGMK-TMP1-A (aliquot MP2PRT-PARGMK-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARGMK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 5.2 years (1,903 days).
Specimen MP2PRT-PARGMK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 556a0303-841f-4b67-9d8f-168b576e87d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARGMK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARGMK-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a912bf6-eb7f-4431-b606-757b38d03dd9

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 143/309 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1B | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 127/242 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.093); catalogued as rs201307791; called by muse, mutect2, varscan2
- CPE | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 94/337 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.189); catalogued as rs746645558, COSV101291627, COSV68582199; called by muse, mutect2, varscan2
- CREBBP | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 237/527 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV99269685; called by muse, mutect2, varscan2
- GRIN2A | c.3206C>T p.T1069M | Missense Mutation (SNP) | VAF 181/424 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.832); catalogued as rs777249842, COSV58032094; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IKZF1 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 187/234 reads (80%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58780577; called by muse, mutect2, varscan2
- LPAR3 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375422448; called by muse, varscan2
- TMC5 | c.1234C>T p.R412W (on ENST00000396229 / NM_001105248.1; = p.R166W on NM_024780.5) | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs763938316, COSV99572879; called by muse, mutect2, varscan2
- ZNF429 | c.180A>C p.K60N | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs1257174652; called by muse, mutect2, varscan2
- ANKRA2 | c.210G>C p.K70N | Missense Mutation (SNP) | VAF 107/339 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- FREM3 | c.1075C>A p.Q359K | Missense Mutation (SNP) | VAF 229/731 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- KCNK15 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 105/356 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.493); called by muse, varscan2
- KIAA1217 | c.4033T>C p.F1345L | Missense Mutation (SNP) | VAF 22/457 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- KIF4B | c.618C>G p.N206K | Missense Mutation (SNP) | VAF 196/671 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLA2G4D | c.2176A>G p.I726V | Missense Mutation (SNP) | VAF 200/436 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMD8 | c.194C>A p.A65E | Missense Mutation (SNP) | VAF 58/786 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.655); called by muse, mutect2
- SSH2 | c.1372A>G p.R458G | Missense Mutation (SNP) | VAF 130/418 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANO5 | c.1672T>C p.L558= | Silent (SNP) | VAF 106/220 reads (48%) | called by muse, mutect2, varscan2
- CPEB2 | c.2383T>C p.L795= | Silent (SNP) | VAF 104/323 reads (32%) | called by muse, mutect2, varscan2
- SNRNP70 | c.75G>A p.L25= | Silent (SNP) | VAF 190/445 reads (43%) | called by muse, mutect2, varscan2
- STEAP2 | c.936C>T p.F312= | Silent (SNP) | VAF 112/398 reads (28%) | catalogued as rs371110364; called by muse, mutect2, varscan2
- UNC13A | c.4179G>A p.P1393= | Silent (SNP) | VAF 110/315 reads (35%) | catalogued as rs1184027918; called by muse, mutect2, varscan2
- ZNF783 | c.802+3185C>T | Intron (SNP) | VAF 293/932 reads (31%) | catalogued as rs767863188, COSV65185659; called by muse, varscan2
